FM case AD14651 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/f3e90082-4156-48da-b57b-835fa7b13c87

Male, 68.9 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
